Somatic mutation profile of tumor specimen TARGET-10-PAPGFD-09A (aliquot TARGET-10-PAPGFD-09A-01D) from TARGET case TARGET-10-PAPGFD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,197 days).
Specimen TARGET-10-PAPGFD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa17dd37-01a0-46b0-89d5-e236aaa38d34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPGFD-14A (Bone Marrow Normal), aliquot TARGET-10-PAPGFD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8094204e-15a8-4e1a-a67c-7812495280a7

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITPR1 | c.5553G>C p.K1851N (on ENST00000354582; = p.K1796N on NM_002222.7) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.379); catalogued as COSV56988473; called by muse, mutect2, varscan2
- NEFL | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM099692; called by muse, mutect2, varscan2
- PLCXD3 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs746073648, COSV60610978, COSV60618210; called by muse, mutect2, varscan2
- RTL1 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs373195780, COSV66016651; called by muse, mutect2, varscan2
- VWA3A | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.81); catalogued as rs370872359; called by muse, mutect2, varscan2
- HDAC2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGI2 | c.3547A>G p.I1183V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MASTL | c.546G>C p.L182F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- OSBPL11 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- RAPH1 | c.1114G>C p.E372Q (on ENST00000319170 / NM_213589.3; = p.E424Q on NM_203365.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIM33 | c.2543G>C p.S848T | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TRPM3 | c.3314A>C p.N1105T (on ENST00000357533 / NM_001366142.2; = p.N960T on NM_020952.6) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- UFL1 | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- P2RY1 | c.*506C>T | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- PPARG | c.83-7751G>C | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
